Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A6FZ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A6FZ-01A (Primary Tumor).

[page 1 of 6]
MRN
Name
Encounter Number

Gender F
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-
- B. LEFT OBTURATOR LYMPH NODES-
- C. RIGHT OBTURATOR LYMPH NODES-
- D. BLADDER, BILATERAL TUBES OVARIES AND ANTERIOR VAGINAL WALL-
- E. LEFT DISTAL URETER-NFS-
- F. LEFT DISTAL URETER FS-
- G. RIGHT DISTAL URETER-NFS-
- H. RIGHT DISTAL URETER FS-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-
FIBROADIPOSE TISSUE WITH MICROSCOPIC FOCI OF FAT NECROSIS.
NO LYMPH NODE OR MALIGNANCY SEEN.
- B. LEFT OBTURATOR LYMPH NODES-
TWO LYMPH NODES, NO MALIGNANCY SEEN.
- C. RIGHT OBTURATOR LYMPH NODES-
NINE LYMPH NODES, NO MALIGNANCY SEEN.
- D. BLADDER, BILATERAL TUBES OVARIES AND ANTERIOR VAGINAL WALL-
INVASIVE CARCINOMA, HIGH GRADE, WITH EXTENSION INTO PERIVESICAL
SOFT TISSUE.

TUMOR SITE: POSTERIOR WALL AND DOME, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: IS PRESENT, EXTENSIVE.

Prepared for

ICD-O-3
Carcinoma, urothelial NOS
C67.4 8/20/13
Site Posterior wall & dome of bladder
path C67.4
Posterior wall & dome of bladder C67.4
8/27/13

Per TSS, squamous differentiation
is 15%. BCL

Criteria: per 6/27/13	Yes	No

[page 2 of 6]
GLANDULAR DIFFERENTIATION: IS PRESENT, FOCAL.

TUMOR SIZE: 3.5 CM.

HISTOLOGIC GRADE: 3/3.

EXTRAVESICULAR MASS: NOT PRESENT.

SPECIMEN TYPE: RADICAL CYSTECTOMY, BILATERAL FALLOPIAN TUBES,
OVARIES AND ANTERIOR VAGINAL WALL.

TNM STAGE: pT3a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED: 0
NUMBER EXAMINED: 12

LYMPHATIC (SMALL VESSEL) INVASION: IS SEEN.

ASSOCIATED EPITHELIAL LESIONS: MILD TO MODERATE UROTHELIAL
DYSPLASIA.

NO TUMOR SEEN AT URETERAL, URETHRAL AND SOFT TISSUE MARGINS.

OVARIES WITH SEROUS CYSTADENOFIBROMA, NO MALIGNANCY SEEN.

UNREMARKABLE FALLOPIAN TUBES AND VAGINAL WALL.

E. LEFT DISTAL URETER-NFS-
FIBROADIPOSE TISSUE, NO MALIGNANCY SEEN.

F. LEFT DISTAL URETER FS-
NO CARCINOMA SEEN.

G. RIGHT DISTAL URETER-NFS-
FIBROADIPOSE TISSUE AND ONE LYMPH NODE, NO MALIGNANCY SEEN.
ATHEROSCLEROSIS.

H. RIGHT DISTAL URETER FS-
NO CARCINOMA SEEN.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT DISTAL URETER MARGIN (INKED) - NO CARCINOMA SEEN.

DISTAL RIGHT URETER MARGIN (INKED) - NO CARCINOMA SEEN.
EPITHELIUM CRUSHED.

Prepared for

[page 3 of 6]
FS Performed by

(Frozen Section Signed

Case Clinical Information
TCC BLADDER

Gross Description

A. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" is a yellow fibrofatty tissue fragment measuring 2.5 x 2 x 0.7 cm. The fat is trimmed and no lymph nodes or areas of induration are grossly identified. The specimen is submitted completely in A1-A3.

B. Received in formalin labeled with the patient's name and "left obturator lymph nodes" is a yellow fibrofatty tissue fragment measuring 6.5 x 2 x 1 cm. The fat is trimmed and two probable lymph nodes are grossly identified. The larger measures 1.5 x 0.5 x 0.3 cm and the smaller measures 1.3 x 0.5 x 0.3 cm. The specimen are bisected and submitted completely in B1.

C. Received in formalin labeled with the patient's name and "right obturator lymph nodes" is a yellow fibrofatty tissue fragment measuring 9 x 3 x 0.5 cm. The fat is trimmed and 9 probable lymph nodes are grossly identified. The largest measures 1.3 x 0.8 x 0.3 cm and the smallest measures 0.4 x 0.4 cm. The largest are bisected and submitted completely in C1-C3. The remainder of the specimen is submitted completely in C4.

D. Received in formalin labeled with the patient's name and "bladder, bilateral tubes, ovaries and anterior vaginal wall" is a radical cystectomy specimen with attached bilateral tubes and ovaries and anterior vaginal wall measuring 17 x 15 x 5 cm overall. A portion of the vaginal anterior wall is identified measuring 5 x 3 cm and has a tan-brown mucosa. The urethral resection margin is identified measuring 1 cm in length. Two short stumps of ureters measuring 1 cm in length are identified. The right ovary measures 2.5 x 2 x 1 cm with a cystic to solid consistency. The fallopian tube measures 5 x 0.5 x 0.5 cm. The left ovary measures 2.5 x 2 x 1 cm and has a cystic to solid appearance. The left fallopian tube measures 4.5 x 0.5 x 0.5 cm and has a fimbriated edge. The bladder is opened anteriorly to show an ulcerated exophytic friable mass measuring 3.5 x 2.5 x 1.2 cm which occupies the posterior bladder wall and floor. The soft tissue resection margin deep to the tumor is somewhat retracted. The specimen is inked blue on the right and black on

Prepared for

[page 4 of 6]
the left. The stump of the ureter is grossly identified and has a stitch measuring 1 cm in length. Sectioning into the mass shows that it invades the muscularis and appears less than 0.1 cm from the fatty posterior tissue. The right ovary is serially sectioned showing a cystic parenchyma. The right fallopian tube is serially sectioned showing an unremarkable pinpoint lumen. The left ovary is serially sectioned showing a cystic parenchyma. The left fallopian tube is serially sectioned showing a pinpoint and unremarkable lumen. No uterus is identified. No lymph nodes are grossly identified in the fatty tissue. The specimen is represented as follows: urethral margin shaved and submitted in D1; mass represented in D2-D9; left lateral wall in D10; left trigone in D11; right lateral wall in D12; section of vaginal wall in relation to the bladder in D13-D14; right ovary in D15; right fallopian tube and fimbria in D16; left ovary represented in D17; left fimbria and fallopian tube represented in D18.

E. Received in formalin labeled with the patient's name and "left distal ureter-NFS" is a grey-tan fibrofatty tissue fragment measuring 1 x 0.5 cm. Submitted completely in E1.

F. Received in formalin labeled with the patient's name and "left distal ureter-FS" is a grey-tan frozen section tissue fragment measuring 0.7 x 0.5 cm. Submitted in F1.

G. Received in formalin labeled with the patient's name and "right distal ureter-NFS" are two grey-tan fibrofatty tissue fragments, the larger measuring 4 x 1 x 0.3 cm and the smaller measuring 2.5 x 1 x 0.3 cm. The specimen is serially sectioned showing a tubular structure with a pinpoint lumen. The specimen is submitted completely in G1-G3.

H. Received in formalin labeled with the patient's name and "right distal ureter-FS" are two frozen section tissue fragments, the larger measuring 1 x 0.5 cm and the smaller measuring 0.5 x 0.5 cm. Wrapped and entirely submitted in H1.

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
- H&E X1
- B. AA ROUTINE H&E X1 BLOCK
- H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1

Prepared for

[page 5 of 6]
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
D. AA ROUTINE H&E X1 BLOCK.5
H&E X1
D. AA ROUTINE H&E X1 BLOCK.6
H&E X1
D. AA ROUTINE H&E X1 BLOCK.7
H&E X1
D. AA ROUTINE H&E X1 BLOCK.8
H&E X1
D. AA ROUTINE H&E X1 BLOCK.9
AA RECUT H&E X1
D. AA ROUTINE H&E X1 BLOCK.10
H&E X1
D. AA ROUTINE H&E X1 BLOCK.11
H&E X1
D. AA ROUTINE H&E X1 BLOCK.12
H&E X1
D. AA ROUTINE H&E X1 BLOCK.13
H&E X1
D. AA ROUTINE H&E X1 BLOCK.14
H&E X1
D. AA ROUTINE H&E X1 BLOCK.15
H&E X1
D. AA ROUTINE H&E X1 BLOCK.16
H&E X1
D. AA ROUTINE H&E X1 BLOCK.17
H&E X1
D. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK
H&E X1
G. AA ROUTINE H&E X1 BLOCK.1

Prepared for:

[page 6 of 6]
H&E X1
G. AA ROUTINE H&E X1 BLOCK.2
H&E X1
G. AA ROUTINE H&E X1 BLOCK.3
H&E X1
H. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared for

Source: NCI Genomic Data Commons file cc0dfdb1-cc2b-4550-b4b5-75bdcd6ada02 (TCGA-K4-A6FZ.16FB3E38-2BB2-4DE2-8DCF-AF6C9225DFC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).